FM case AD1763 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/78e35cb3-5879-4c8f-9705-02e70f791e0a

Male, 63.8 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the gastrointestinal tract; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
